OHSU case 4088 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/37b6dc02-3602-4e83-90e3-6980973f655b

Demographics
Sex at birth: female.

Diagnoses (1)
1. Chronic myelomonocytic leukemia, NOS: ICD-O-3 morphology code: 9945/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Age at diagnosis: 77.0 years (28,124 days); Days to last follow up: 1,796 days (4.9 years).

Biospecimens (1 sample)
- Sample 1309D: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
